Somatic mutation profile of tumor specimen TCGA-25-2393-01A (aliquot TCGA-25-2393-01A-01W-0799-08) from TCGA case TCGA-25-2393, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.0 years (29,585 days).
Specimen TCGA-25-2393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9058af97-aa21-40b2-bace-da5d022142e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2393-10A (Blood Derived Normal), aliquot TCGA-25-2393-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc85bcba-dedf-403c-b89d-5be97c01ec64

The open-access MAF lists 87 somatic variants for this specimen: 71 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 13, Frame Shift Del 4, Nonsense Mutation 4, In Frame Del 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.411_425del p.A138_P142del | In Frame Del (DEL) | VAF 145/193 reads (75%) | hotspot (GDC flag); catalogued as COSV52796869; called by mutect2, pindel, varscan2
- AACS | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55535077; called by muse, mutect2, varscan2
- ABCA6 | c.4601C>T p.A1534V | Missense Mutation (SNP) | VAF 2211/2468 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52636470; called by mutect2, varscan2
- ABCA9 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.098); catalogued as COSV60621639; called by muse, mutect2, varscan2
- AKR7A3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs756610725, COSV64389201; called by muse, mutect2, varscan2
- ANO1 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV60282007; called by mutect2, varscan2
- ARL6IP5 | c.453A>C p.K151N | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as COSV56234488; called by muse, mutect2, varscan2
- ARPP21 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as rs142886822; called by muse, mutect2, varscan2
- ARRDC1 | c.229+1G>T p.X77_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101004539; called by muse, mutect2, varscan2
- BCORL1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54391115, COSV54392951; called by muse, mutect2, varscan2
- C22orf42 | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.567); catalogued as COSV66075416, COSV66076460; called by muse, mutect2, varscan2
- CCDC82 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs776916861, COSV53592460; called by muse, mutect2, varscan2
- CCNT2 | c.1808T>G p.V603G | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV51471368; called by muse, mutect2, varscan2
- CCT8L2 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 68/1254 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV63463873, COSV63463977; called by muse, mutect2
- CELSR2 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54768158; called by muse, mutect2, varscan2
- CFAP43 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs551332560, COSV53376775; called by muse, mutect2, varscan2
- CLIP4 | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 48/907 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100191927, COSV100191975; called by muse, mutect2
- COL4A4 | c.3521C>T p.P1174L | Missense Mutation (SNP) | VAF 272/426 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61630199; called by muse, mutect2, varscan2
- CSN3 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 106/416 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV59243648, COSV59244130; called by muse, mutect2, varscan2
- DDO | c.691G>A p.V231I (on ENST00000368924 / NM_001368172.1; = p.V172I on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs751668367, COSV64469787; called by muse, mutect2, varscan2
- DNHD1 | c.13582C>G p.L4528V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54431659; called by muse, mutect2, varscan2
- FCGBP | c.9328G>A p.V3110I | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as rs547191912; called by muse, mutect2, varscan2
- FILIP1L | c.2465T>C p.V822A (on ENST00000354552 / NM_182909.3; = p.V582A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 557/2698 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs753645955, COSV58765804; called by muse, mutect2, varscan2
- FUT1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751122055, COSV59567643; called by muse, mutect2, varscan2
- GARRE1 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 439/668 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55097342; called by muse, mutect2, varscan2
- HSPA4L | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.715); catalogued as rs756784442, COSV56544147; called by muse, mutect2, varscan2
- IGHG4 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218452317; called by muse, mutect2, varscan2
- IL3RA | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.266); catalogued as COSV58430086; called by muse, mutect2, varscan2
- JCAD | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as COSV100948413; called by muse, mutect2, varscan2
- JMJD1C | c.6274T>C p.Y2092H | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59513380; called by muse, mutect2, varscan2
- MACF1 | c.5611C>G p.L1871V | Missense Mutation (SNP) | VAF 186/691 reads (27%) | catalogued as rs1293417526, COSV57110163; called by muse, mutect2, varscan2
- MCM4 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474445101, COSV50621643; called by muse, mutect2, varscan2
- MED12 | c.5200C>T p.P1734S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV100378327; called by muse, mutect2, varscan2
- MTA1 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1430974785, COSV100495231; called by muse, mutect2, varscan2
- NXPH1 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1378631255, COSV68312136; called by muse, mutect2, varscan2
- OR10W1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 175/490 reads (36%) | catalogued as COSV101223688; called by muse, mutect2, varscan2
- PAX8 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99639622; called by muse, mutect2, varscan2
- PIGK | c.833G>A p.S278N | Missense Mutation (SNP) | VAF 95/150 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV63061679; called by muse, mutect2, varscan2
- PLCB2 | c.933C>G p.H311Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV53031417; called by muse, mutect2, varscan2
- PLCZ1 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99856453; called by muse, mutect2
- PLOD1 | c.939C>G p.Y313* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99538377; called by muse, mutect2, varscan2
- PRKCQ | c.1495G>T p.G499* | Nonsense Mutation (SNP) | VAF 151/355 reads (43%) | catalogued as COSV54107618; called by muse, mutect2, varscan2
- PTPRB | c.5965C>G p.H1989D | Missense Mutation (SNP) | VAF 14/449 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV99717684; called by muse, mutect2
- RAB3IP | c.297C>T p.I99= (on ENST00000550536 / NM_175623.4; = p.I83= on NM_022456.5) | Splice Region (SNP) | VAF 32/518 reads (6%) | catalogued as COSV99923303; called by muse, mutect2
- RB1CC1 | c.4162G>T p.E1388* | Nonsense Mutation (SNP) | VAF 89/206 reads (43%) | catalogued as COSV50243734; called by muse, mutect2, varscan2
- RNF43 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV68457236, COSV68460830; called by mutect2, varscan2
- SCN2A | c.1553A>G p.E518G | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.155); catalogued as COSV51834657; called by muse, mutect2, varscan2
- SHROOM2 | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV101098736; called by muse, mutect2, varscan2
- SI | c.4976A>C p.Y1659S | Missense Mutation (SNP) | VAF 186/706 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100015801; called by muse, mutect2, varscan2
- SLC11A1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV51916024; called by muse, mutect2, varscan2
- SLC19A3 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 99/593 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV51451750; called by muse, mutect2, varscan2
- SLC2A12 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV51598301; called by muse, mutect2, varscan2
- SP140 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 86/606 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs778173710, COSV59447201; called by muse, mutect2, varscan2
- SYNE1 | c.6975A>C p.E2325D (on ENST00000367255 / NM_182961.4; = p.E2332D on NM_033071.3) | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99566950; called by muse, mutect2, varscan2
- TAS2R42 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 68/704 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100516877; called by muse, mutect2
- TECR | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs367816943; called by muse, mutect2, varscan2
- TENM1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 630/2539 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV64426844; called by muse, varscan2
- TF | c.1089G>T p.W363C | Missense Mutation (SNP) | VAF 200/503 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753776946, COSV53918362; called by muse, mutect2, varscan2
- TRPA1 | c.833T>C p.F278S | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51556793; called by muse, mutect2, varscan2
- ZC3H14 | c.169A>T p.N57Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51767576; called by muse, mutect2, varscan2
- ZNF536 | c.2611G>C p.G871R | Missense Mutation (SNP) | VAF 75/456 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.905); catalogued as COSV62820105; called by muse, mutect2, varscan2
- ASRGL1 | c.211_212insAA p.T71Kfs*29 | Frame Shift Ins (INS) | VAF 33/136 reads (24%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.240_251del p.F81_V84del | In Frame Del (DEL) | VAF 19/154 reads (12%) | called by mutect2, pindel, varscan2
- FPGT | c.938_943del p.A313_Y314del | In Frame Del (DEL) | VAF 45/189 reads (24%) | called by mutect2, pindel, varscan2
- GDPD3 | c.140-9_143del p.X47_splice | Splice Site (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 204/1046 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, varscan2
- LAMA3 | c.2623_2633del p.L875Rfs*31 | Frame Shift Del (DEL) | VAF 21/169 reads (12%) | called by mutect2, pindel, varscan2
- LAMC3 | c.2251_2294del p.D751Hfs*22 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2*, pindel
- LRP1B | c.1602dup p.V535Cfs*2 | Frame Shift Ins (INS) | VAF 192/823 reads (23%) | called by mutect2, pindel, varscan2
- MEA1 | c.372_396del p.L125Wfs*6 | Frame Shift Del (DEL) | VAF 22/187 reads (12%) | called by mutect2, pindel
- PRDM16 | c.772del p.A258Lfs*86 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel
- ATP2B3 | c.489C>T p.S163= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs1557006528, COSV54842033; called by muse, mutect2, varscan2
- CD101 | c.165T>C p.H55= | Silent (SNP) | VAF 91/375 reads (24%) | catalogued as COSV99869755; called by muse, mutect2, varscan2
- DCLRE1C | c.261C>A p.I87= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs191086777, COSV63182246; called by muse, mutect2, varscan2
- HEATR5B | c.1833T>A p.R611= | Silent (SNP) | VAF 36/760 reads (5%) | catalogued as COSV99249459; called by muse, mutect2
- MAPK6 | c.1029T>A p.L343= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV99959245; called by muse, mutect2
- OR2G6 | c.396C>T p.Y132= | Silent (SNP) | VAF 144/482 reads (30%) | catalogued as COSV58573884; called by muse, mutect2, varscan2
- OR2G6 | c.768A>T p.I256= | Silent (SNP) | VAF 183/681 reads (27%) | catalogued as COSV58573890; called by muse, mutect2, varscan2
- OR5AS1 | c.549T>C p.P183= | Silent (SNP) | VAF 622/1482 reads (42%) | catalogued as COSV57981058; called by muse, varscan2
- PIWIL1 | c.1980A>C p.S660= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV55344822; called by muse, mutect2, varscan2
- SCNN1B | c.1458C>A p.T486= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV56302262; called by muse, mutect2, varscan2
- TGFBR1 | c.723G>T p.S241= | Silent (SNP) | VAF 236/641 reads (37%) | catalogued as rs201112150, COSV100895333, COSV66625093; called by muse, varscan2
- UTP14C | c.1368C>T p.S456= | Silent (SNP) | VAF 126/299 reads (42%) | catalogued as rs757961978, COSV73000593; called by muse, mutect2, varscan2
- VSTM4 | c.792G>A p.T264= | Silent (SNP) | VAF 819/3070 reads (27%) | catalogued as rs780534686, COSV100251771; called by muse, mutect2, varscan2
- C9orf129 | n.580C>T | RNA (SNP) | VAF 30/107 reads (28%) | catalogued as rs769775497, COSV100962402; called by muse, mutect2, varscan2
- H2AC12 | c.-2G>C | 5'UTR (SNP) | VAF 88/324 reads (27%) | called by muse, mutect2, varscan2
- TLE4 | c.391-2764A>T | Intron (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
